TCGA case TCGA-46-3767 — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: St. Joseph's Medical Center (MD). Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6b0b6fc0-d808-49c3-8f2a-e122bc3142f5

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 76 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C34.3; Tissue or organ of origin: Lower lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 76.4 years (27,912 days); Year of diagnosis: 2009; AJCC pathologic T: T1a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 396 days (1.1 years); Sites of involvement: Central Lung.
   Pathology details: Consistent pathology review: Yes.

Follow-up (2 entries)
- Days to follow up: 388 days (1.1 years); Disease response: Tumor Free.
- Days to follow up: 396 days (1.1 years); Disease response: Tumor Free.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-46-3767-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.8; Intermediate dimension: 0.8; Shortest dimension: 0.1.
  Slide TCGA-46-3767-01A-01-TS1: Section location: Top; Percent tumor cells: 65; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 30.
  Slide TCGA-46-3767-01A-01-BS1: Section location: Bottom; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 25.
- Sample TCGA-46-3767-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-46-3767-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Tobacco smoking history indicator: 3; Anatomic organ subdivision: L-Lower; Location lung parenchyma: Central Lung; KRAS gene analysis indicator: No; EGFR mutation status: No; Eml4 alk translocation status: No.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 396 days; disease-specific survival: no event (censored), 396 days; disease-free interval: no event (censored), 396 days; progression-free interval: no event (censored), 396 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-46-3767-01A-01D-0978-01): tumor purity 0.23, ploidy 2.14, whole-genome doublings 0.
